Somatic mutation profile of tumor specimen TCGA-HT-7690-01A (aliquot TCGA-HT-7690-01A-11D-2253-08) from TCGA case TCGA-HT-7690, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 29.2 years (10,673 days).
Specimen TCGA-HT-7690-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 157b620c-69db-4644-8d01-250c7791930d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7690-10A (Blood Derived Normal), aliquot TCGA-HT-7690-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b64b38b-bc5e-44c2-982b-fe6bf2cc321f

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 16, Silent 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 42/115 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 82/106 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADRA1B | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60702566; called by muse, mutect2, varscan2
- ATRX | c.6055A>G p.K2019E | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64878656; called by muse, mutect2, varscan2
- CNOT6L | c.604G>A p.A202T (on ENST00000504123 / NM_001286790.2; = p.A197T on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV53701110; called by muse, mutect2, varscan2
- EPPK1 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs377622455; called by muse, mutect2
- KCNB2 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV73051019; called by muse, mutect2
- KEL | c.164T>G p.L55W | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs780610965, COSV62335875; called by muse, mutect2, varscan2
- MATK | c.817T>G p.F273V (on ENST00000310132 / NM_139355.3; = p.F274V on NM_002378.4) | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59555320; called by muse, mutect2, varscan2
- NOTCH2 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs587595062, COSV56694922; called by muse, mutect2
- PI3 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as rs780306943, COSV54783016, COSV54783391; called by muse, mutect2, varscan2
- PKHD1 | c.7349A>G p.K2450R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV61882397; called by muse, mutect2, varscan2
- RNF43 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 74/161 reads (46%) | catalogued as rs747063415, COSV68458782; called by muse, mutect2, varscan2
- SLC30A2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 109/248 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs779800415, COSV100958639, COSV65332725; called by muse, mutect2, varscan2
- SLIT1 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56591765; called by muse, mutect2, varscan2
- XCL1 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.047); catalogued as COSV63192414; called by muse, mutect2, varscan2
- ZNF667 | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV52635921; called by muse, mutect2
- TBC1D17 | c.1306del p.D436Mfs*24 | Frame Shift Del (DEL) | VAF 31/126 reads (25%) | called by mutect2, pindel*, varscan2
- ABCC11 | c.3360G>A p.S1120= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs552190839, COSV100750917, COSV62324071; called by muse, mutect2, varscan2
- ATP11C | c.2016A>G p.K672= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV59567298; called by muse, mutect2, varscan2
- MARCHF10 | c.87T>C p.Y29= | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as COSV60888398; called by muse, varscan2
- MOB3A | c.591C>T p.F197= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV63865498; called by mutect2, varscan2
